Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A7S9, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A7S9-01A (Primary Tumor).

[page 1 of 2]
(Verified)

A. Liver, segmentectomy :

.HEPATOCELLULAR CARCINOMA

Tumor number: one

Satellite nodule: no

Location :

Gross type: expanding nodular

Size(cm): 2.3x1.9cm

Differentiation: The worst differentiation: Edmondson grade III

Differentiation: The major differentiation: Edmondson grade II

Histologic type : microtrabecular

Cell type : hepatic

Tumor necrosis : no

Hemorrhage : no

Fatty change : no

Fibrous capsule : complete

Infiltration of capsule : yes

Septum formation : yes

Surgical margin invasion : no(margin of the clearance 0.5 cm)

Serosa invasion: no

Portal vein invasion : no

Bile duct invasion : no

Hepatic vein invasion : no

Hepatic artery invasion : no

Microvessel invasion : no

Intrahepatic metastasis : no

Multicentric occurrence : no

T stage : pII

.Non-tumor liver

Chronic hepatitis : yes

Etiology : HBV

Grade, lobular : minimal

Grade, portoperiportal : none

Stage(fibrosis) : cirrhosis

Cirrhosis : mixed

B. Gallbladder, cholecystectomy:

. Chronic cholecystitis, mild

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver
C22.0

Q410/4/13

[page 2 of 2]
< Immunohistochemical and special stain results>

Hepatocyte (block A1): Positive in tumor cells
Cytokeratin 19 (block A1): Negative in tumor cells
Cytokeratin 7 (block A5): Positive in bile duct
Iron (block A5): Negative
Cytokeratin 7 (block A4) : Negative

- A. The specimen received in formalin consists of a product of liver segmentectomy, measuring 6.3x6.2x2.2cm. The capsule is intact. A vaguely nodular type solid tumor is noted, measuring 2.5x2.0cm. The cut surface of tumor is grayish homogenous without necrosis. The remaining parenchyma shows cirrhosis. Representative sections are embedded, (A1 and 2- tumor one plane, A3 and 4- tumor one plane, A5- cirrhotic parenchyma)
- B. The specimen received in formalin consists of a previously gallbladder, measuring 5.5cm in length and 2cm in diameter. The wall measures 0.3cm in maximal thickness. The mucosa is greenish velvety. There is no stone or polyp. Representative sections are embedded.

H&E(6, MT(1), RTC(1), D-PAS(1), Iron(1), Cytokeratin 7(1), Hepatocyte(1), Cytokeratin 19 (1), Cytokeratin 7(1)

Source: NCI Genomic Data Commons file 4ca9ec8d-b33f-4ef0-9b55-c5de56e20986 (TCGA-RC-A7S9.A537996A-E747-4906-B488-43181F3C7E17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).